Somatic mutation profile of tumor specimen C3N-00326-01 (aliquot CPT0022530006) from CPTAC case C3N-00326, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 45.1 years (16,460 days).
Specimen C3N-00326-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea9f8aaf-bb1c-46b8-bfc0-388d029f9d47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00326-31 (Blood Derived Normal), aliquot CPT0019690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af981ddf-de79-4777-a313-dfa619c867e9

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, Frame Shift Ins 2, Frame Shift Del 2, In Frame Del 1, Nonsense Mutation 1, 3'UTR 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/336 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1345_1356del p.P449_L452del | In Frame Del (DEL) | VAF 35/110 reads (32%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.71A>G p.D24G | Missense Mutation (SNP) | VAF 110/315 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs797044910, CM110138, CM141438, COSV64293188, COSV64296384, COSV64307484; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BIRC6 | c.13961G>A p.R4654Q | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70205970; called by muse, mutect2, varscan2
- HMCN2 | c.11303G>A p.G3768D | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.308); catalogued as rs1225352026; called by muse, mutect2, varscan2
- PIGF | c.164A>G p.N55S | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.137); catalogued as rs757730689; called by muse, mutect2, varscan2
- PRB2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.031); catalogued as rs199748368; called by muse, varscan2
- SSX7 | c.434C>A p.P145Q | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs138008347, COSV53339605; called by muse, mutect2, varscan2
- ARID5B | c.1274del p.Q425Rfs*54 | Frame Shift Del (DEL) | VAF 42/145 reads (29%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.1193A>C p.D398A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- DSP | c.4684dup p.S1562Ffs*65 | Frame Shift Ins (INS) | VAF 100/342 reads (29%) | called by mutect2, pindel, varscan2
- GRIN3A | c.2884C>T p.R962* | Nonsense Mutation (SNP) | VAF 145/391 reads (37%) | called by muse, mutect2, varscan2
- MAGEC1 | c.374A>T p.Q125L | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PTEN | c.263_264del p.Y88Sfs*3 | Frame Shift Del (DEL) | VAF 88/316 reads (28%) | called by pindel, varscan2
- SEC24C | c.2383_2384insTC p.H795Lfs*36 | Frame Shift Ins (INS) | VAF 69/224 reads (31%) | called by mutect2, pindel, varscan2
- ARHGEF3 | c.1473T>C p.S491= | Silent (SNP) | VAF 77/243 reads (32%) | catalogued as rs889689320; called by muse, mutect2, varscan2
- ATP10A | c.687C>T p.S229= | Silent (SNP) | VAF 85/258 reads (33%) | catalogued as rs1206302817, COSV63518070; called by muse, mutect2, varscan2
- FAM120C | c.786C>T p.S262= | Silent (SNP) | VAF 109/313 reads (35%) | catalogued as rs1388220058, COSV60257804; called by muse, mutect2, varscan2
- IGHV3-49 | c.246C>A p.A82= | Silent (SNP) | VAF 84/257 reads (33%) | called by muse, mutect2, varscan2
- IRAG1 | c.1866C>T p.A622= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs781601530; called by muse, mutect2, varscan2
- PURB | c.522G>C p.L174= | Silent (SNP) | VAF 54/192 reads (28%) | called by muse, mutect2, varscan2
- CENPT | c.202-32G>A | Intron (SNP) | VAF 55/176 reads (31%) | catalogued as rs750516820; called by muse, mutect2, varscan2
- NQO1 | chr16:69707176 del G | 3'Flank (DEL) | VAF 28/80 reads (35%) | called by mutect2, pindel*, varscan2
- STX1B | c.*9del | 3'UTR (DEL) | VAF 30/78 reads (38%) | catalogued as rs750392809; called by mutect2, varscan2
